Gene-level copy-number profile of tumor specimen TCGA-77-A5GF-01A from TCGA case TCGA-77-A5GF, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,654 days).
Specimen TCGA-77-A5GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9c7b6939-6a0f-441a-a276-f7a87c7d7bbe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5GF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3d9c1810-4507-4579-bad5-22f1f2140a77

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 29,380; copy number 2: 24,396; copy number 3: 5,497; copy number 4: 217; copy number 5: 64; copy number 6: 18; copy number 7: 69; copy number 8: 60; copy number 9: 101; copy number 10: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-A5GF-01A-21D-A27J-01): tumor purity 0.56, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,039 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr2:38,814–4,945,383, 75 genes, copy number 3 (broad region; genes not listed).
- chr2:114,442,299–117,181,562, 16 genes, copy number 3 (within-gene range 2–3): DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1.
- chr3:118,900,557–128,871,540, 245 genes, copy number 3 (broad region; genes not listed).
- chr3:135,965,728–185,153,060, 788 genes, copy number 3–10 (within-gene range 2–10) (broad region; genes not listed).
- chr6:46,997,708–58,438,364, 175 genes, copy number 3–5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:61,240,898–65,707,226, 30 genes, copy number 4–8 (within-gene range 2–8): AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2.
- chr6:71,886,703–75,919,537, 69 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:82,892,390–89,921,760, 125 genes, copy number 3 (broad region; genes not listed).
- chr6:89,950,116–90,079,734, 3 genes, copy number 3 (within-gene range 1–3): AL121787.1, RN7SKP110, AL158136.1.
- chr8:76,162,119–90,095,475, 192 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr8:91,909,738–93,166,850, 19 genes, copy number 3: PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87.
- chr8:93,215,925–93,234,878, 2 genes, copy number 3: AC016885.1, AC016885.3.
- chr8:94,879,770–96,431,160, 33 genes, copy number 3: CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P.
- chr8:104,478,539–106,060,524, 17 genes, copy number 3 (within-gene range 1–3): AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1.
- chr8:107,857,589–126,008,930, 204 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr8:125,900,951–126,001,001, 3 genes, copy number 3: RNU6-442P, SOD1P3, AC024681.2.
- chr8:126,556,323–127,419,050, 1 gene, copy number 3 (within-gene range 1–3): PCAT1.
- chr8:127,072,694–134,390,487, 96 genes, copy number 3 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 3–4 (broad region; genes not listed).
- chr9:96,450,169–98,796,965, 60 genes, copy number 4 (within-gene range 2–4): HABP4, CDC14B, PRXL2C, AL589843.1, AL589843.2, ZNF510, ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV, TCEA1P1, GAS2L1P2, VN1R51P, FAM220CP, AL445670.1, ANKRD18CP, RNU6-798P, AL590705.3, ZNF322P1, AL590705.1, AL590705.2, SUGT1P4-STRA6LP, STRA6LP, SUGT1P4, AL512590.2, CCDC180, MIR1302-8, AL512590.1, AL512590.3, TDRD7, TMOD1, AL162385.1, TSTD2, NCBP1, AL162385.2, XPA, KRT18P13, PTCSC2, AL445531.1, FOXE1, TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6.
- chr11:79,987,513–79,989,630, 1 gene, copy number 4: AP001284.1.
- chr16:59,540,126–64,738,564, 38 genes, copy number 3: RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1.
- chr16:82,035,004–83,819,737, 23 genes, copy number 3 (within-gene range 2–3): HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190, AC009117.1, AC009117.2, CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4, AC009063.2, AC009063.1, AC009119.1, HSBP1.
- chr19:30,553,956–40,898,282, 444 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26,959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
